TCGA case TCGA-EL-A3MX — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ea2c873a-ea52-4920-8d20-554d5fa8ddc1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 1,753 days (4.8 years).

Diagnoses (6)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 66.2 years (24,178 days); Year of diagnosis: 2004; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 6; Tumor width measurement: 5.5.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 35 days; Days to treatment end: 35 days; Treatment dose: 106 mCi; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 1,716 days (4.7 years); Days to treatment end: 1,716 days (4.7 years); Treatment dose: 800 cGy; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Recorded as not given: adjuvant I-131 Radiation Therapy; adjuvant Pharmaceutical Therapy, NOS.
2. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Head, face or neck, NOS. Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: I-131 Radiation Therapy, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Liver. Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: I-131 Radiation Therapy, for progressive disease; Surgery, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Lung, NOS. Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: I-131 Radiation Therapy, for progressive disease; Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Pleura, NOS. Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: I-131 Radiation Therapy, for progressive disease; Surgery, NOS, for progressive disease.
6. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Long bones of lower limb and associated joints. Age at diagnosis: 70.9 years (25,886 days); Days to diagnosis: 1,708 days (4.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,708 days (4.7 years).
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Initial disease status: Progressive Disease.
   Recorded as not given: I-131 Radiation Therapy, for progressive disease; Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (8 entries)
- Day 1,708 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Long bones of lower limb and associated joints; Days to progression: 1,708 days (4.7 years); Evidence of progression type: Histologic Confirmation.
- Days to follow up: 1,753 days (4.8 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pleura, NOS; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.
- Imaging type: MRI; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Evidence of progression type: Histologic Confirmation; Timepoint: Initial Diagnosis.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Head, face or neck, NOS; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EL-A3MX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 260 mg.
  Slide TCGA-EL-A3MX-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-EL-A3MX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EL-A3MX-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 180 mg.
  Slide TCGA-EL-A3MX-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 6; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Metastasis site: Lung; I 131 radiation first treatment method: Patient did not receive I-131 treatment.
- Neoplasm dimension: Tumor size width: 6; Tumor size width: 4.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: MRI with contrast; Lymph nodes preop imaging type: MRI without contrast.
- Metastatic neoplasm confirmed diagnosis method names: Metastatic diagnosis confirmed by: Biopsy Proven.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,753 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,753 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,708 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EL-A3MX-01A-11D-A219-01): tumor purity 0.65, ploidy 2.02, whole-genome doublings 0.
